Gene-level copy-number profile of tumor specimen C3L-01275-01 from CPTAC case C3L-01275, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 65.1 years (23,768 days).
Specimen C3L-01275-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a505157d-06fa-4802-b485-c7261cae2faf.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-01275-72 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/0639a4c1-2a42-4402-9217-b9c3f7747bdc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 19; copy number 1: 104; copy number 2: 58,214; copy number 3: 60.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:145,233,001–145,405,778, 7 genes: AC241585.1, PPIAL4D, AC245014.2, RNVU1-14, AC245014.3, AC245014.1, NBPF20.
- chr2:110,375,138–110,612,404, 11 genes: LINC01106, ZBTB45P2, GPAA1P2, AC112229.4, AC112229.1, AC112229.3, LIMS4, AC112229.2, AC108938.1, RGPD6, AC226101.1.
- chr5:139,299,852–139,299,968, 1 gene (within-gene range 0–2): RNA5SP195.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 97. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
